Surgical pathology report (de-identified scan), TCGA case TCGA-CC-A5UD, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site ILSBio, specimen TCGA-CC-A5UD-01A (Primary Tumor).

[page 1 of 5]
Clinical Case Report

(For Collection of Cancerous Tissue)

et cetera ICD-O-3 NO
Carcinoma, hepatocellular
8170/3
path
Carcinoma, hepatocellular
Solid type 8170/3
Site: Liver, hepatic NOS
QW 4/2/13 C22.0

I personally informed this patient that a specimen(s) would be collected to be used for research purposes. I reviewed the **RESEARCH SUBJECT INFORMATION AND CONSENT FORM** with the patient and answered any questions the patient had. The patient then signed the consent form as a free and voluntary act. A copy of this informed consent document will be retained at our institution.

Name of Physician or Study Coordinator

Signature

Date

Clinical Information

GENERAL INFORMATION				
Date of Birth (mm/dd/yyyy)	Height	Marital Status	Race	Temperature
Gender	Weight	☐ Single ☒ Married	WHITE	
☒ Male ☐ Female	62 kg	☐ Divorced ☐ Widow	Blood Pressure	Heart Rate
			116	

HISTORY OF PRESENT ILLNESS
Chief Complaints: Abdominal pain; fever
Symptoms: Weakness; Weight loss
Clinical Findings:
Performance Scale (Karnofsky Score):
☐ 100 Asymptomatic ☒ 80-90 Symptomatic but Fully Ambulatory ☐ 60-70 Symptomatic, in bed less than 50% of day ☐ 40-50 Symptomatic, in bed more than 50% of day, but not bed ridden ☐ 20-30 Bed Ridden

CURRENT MEDICATIONS				
Drug	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 2 of 5]
PAST MEDICAL HISTORY			
Diagnosis/Disease/Disorder/Injury	Diagnosis Date	Treatment	Status

OB/GYN HISTORY		
Menopausal Status	Date of First Menses	# of Pregnancies
☐ Pre-menopausal		
☐ Peri-Menopausal	Date of Last Menses	# of Live Births
☐ Post-menopausal		
Birth Control: ☐ Condom ☐ Oral Contraceptive ☐ IUD ☐ Other: _____		Hormone Replacement Therapy: _____

SOCIAL HISTORY				
Occupation:		Environmental Hazards:		
Smoking History				
Current Status	TYPE	Packs/day	Duration	When Quit
☒ YES ☐ NO		2 p/day	25 (yrs)	Still smoke (yrs)
Alcohol Consumption				
Current Status	TYPE	Drinks/day	Duration	When Quit
☒ YES ☐ NO		1 drink/day	20 (yrs)	4 months ago
Drug Use				
Current Status	TYPE	Frequency	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)

FAMILY MEDICAL HISTORY		
Relative	Diagnosis	Age of Diagnosis

LAB DATA						
Test	Result	Date	Test	Result	Date	
HIV	☒ Negative ☐ Positive: _____		CEA	☐ Negative ☐ Positive: _____		
Hep B	☒ Negative ☐ Positive: _____		CA 15-3	☐ Negative ☐ Positive: _____		
Hep C	☒ Negative ☐ Positive: _____		CA 19-9	☐ Negative ☐ Positive: _____		
AFP	☐ Negative ☐ Positive: _____		PSA	☐ Negative ☐ Positive: _____		
Other:	☐ Negative ☐ Positive: _____		Other:	☐ Negative ☐ Positive: _____		
B/T Cell Markers:						

[page 3 of 5]
DIAGNOSTIC STUDIES		
Study	Results	Date
Ultrasound X	A tumor was found in the liver	
X-Ray		
CT		
Endoscopy		
MRI		
Biopsy		

CLINICAL DIAGNOSIS		
Preoperative Clinical Diagnosis		
Liver Cancer		
Location of Suspected Involved Lymph Nodes	Location of Suspected Distant Metastasis	
Clinical Staging		Date of Diagnosis
T ₃ N ₀ M ₀ Stage: III A		

Treatment Information

SURGICAL TREATMENT			
Procedure			Date of Procedure
ReSection of the right liver			
Primary Tumor			
Organ	Detailed Location	Size	
Liver tumor	Right	8 x 6 x 5 cm	
Extension of Tumor			
Lymph Nodes			
Description	Location of Lymph Nodes	# of Lymph Nodes	
Palpable, Non-Dissected Lymph Nodes			
Dissected Lymph Nodes			
Distant Metastasis			
Organ	Detailed Location	Size	
Surgical Staging			
T ₃ N ₀ M ₀ Stage: III			

NEOADJUVANT THERAPY (Chemo, Radiation, Immuno, Hormonal, or Molecular)				
Drug/Treatment	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 4 of 5]
Pathology Form

Specimen Information

Collected by: ____

____ Date:

Time: ____

Preserved by: ____

____ Date

Time: ____

SPECIMEN TYPE (# of samples provided)							
Frozen		Paraffin Block		Blood/Serum/Plasma		Slide	
Diseased	Normal	Diseased	Normal	Diseased	Normal	Diseased	Normal
4	0	4	0			4	0
Time to LN2		Time to Formalin		Time to LN2			
11 min		12 min					

PATHOLOGICAL DESCRIPTION			
Primary Tumor			
Organ	Size	Extension of Tumor	Distance to NAT
Liver Tumor	8 x 6 x 5 cm	Right	cm
Lymph Nodes			
Location	# Examined	# Metastasized	
Distant Metastasis			
Organ	Detailed Location	Size	
Pathological Staging			
pT 3	N ₀	M ₀	Stage: III

Notes:

[page 5 of 5]
Consolidated Pathology Diagnosis

ID#: _____

Histological Pattern									
Cell Distribution			Structural Pattern						
	+	-		+	-				
Diffuse		☒	Streaming						
Mosaic	☒		Storiform						
Necrosis	☒		Fibrosis						
Lymphocytic Infiltration	☒		Pallisading						
Vascular Invasion		☒	Cystic Degeneration						
Clusterized	☒		Bleeding						
Alveolar Formation		☒	Myxoid Change						
Indian File		☒	Psammoma/Calcification						

Cellular Differentiation											
Squamous	+	-	Adenomatous	+	-	Sarcomatous	+	-	Lymphomatous	+	-
Squamoid Cell			Glandular cell	☒		Round Cell			Large Cell		
Spindle Cell			Cell Stratification	☒		Fibroblast			Small Cell		
Keratin			Secretion	☒		Osteoblast			RS Cell/RS Like		
Desmosome			Intracyt. Vacuole	☒		Lipoblast			Inflam. Cell		
Pearl			Gland formation		☒	Myoblast			Plasma Cell		

Cellular Differentiation: ☐ Well ☒ Moderate ☐ Poor

Nuclear Appearance				
Nuclear Atypia:	0	I	II	III
Aniso Nucleosis			☒	
Hyperchromatism			☒	
Nucleolar Prominent			☒	
Multinucleated Giant Cell			☒	
Mitotic Activity			☒	

Nuclear Grade: ☒ 0 ☐ I ☐ II ☐ III

D₁ 70% D₂ 70% D₃ 70% D₄ 75% , Neurons 2%

Final Pathology Report

Histological Diagnosis: Hepatocellular Carcinoma Grade: 2
Solid type

Comments:

Director, Research Pathology

Date

Source: NCI Genomic Data Commons file 9ab33ab2-8c02-47f6-a062-c61dccac5f03 (TCGA-CC-A5UD.77BF208C-F5ED-4A05-BFDE-36063F43E022.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).